Somatic mutation profile of tumor specimen TCGA-BF-A3DJ-01A (aliquot TCGA-BF-A3DJ-01A-11D-A20D-08) from TCGA case TCGA-BF-A3DJ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 36.5 years (13,332 days).
Specimen TCGA-BF-A3DJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6b1c957-8bbb-4e91-aee4-11da91e3a9bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A3DJ-10A (Blood Derived Normal), aliquot TCGA-BF-A3DJ-10A-02D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49f20c2a-58e4-46dc-b03e-1af51b7588d4

The open-access MAF lists 163 somatic variants for this specimen: 112 protein-altering or splice-affecting, 47 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 47, Nonsense Mutation 7, Splice Site 4, RNA 3, Splice Region 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FAR1 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as rs724159962, CM1411742, COSV61384024; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.2557C>T p.R853C | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs764738392, COSV60622460, COSV60628108; called by muse, mutect2, varscan2
- ACKR1 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV63672790; called by muse, mutect2, varscan2
- ADAMTS20 | c.3381G>A p.Q1127= | Splice Region (SNP) | VAF 12/31 reads (39%) | catalogued as rs1215173305, COSV67131527; called by muse, mutect2, varscan2
- ADGRL1 | c.3979G>T p.G1327C (on ENST00000340736 / NM_001008701.3; = p.G1322C on NM_014921.5) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV61564722; called by muse, mutect2, varscan2
- AK9 | c.5269C>T p.R1757C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs775310575, COSV69851307; called by muse, mutect2, varscan2
- ALMS1 | c.7342C>T p.P2448S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52508882; called by muse, mutect2, varscan2
- ARID2 | c.2173C>T p.Q725* | Nonsense Mutation (SNP) | VAF 42/107 reads (39%) | catalogued as COSV57603793, COSV57616521; called by muse, mutect2, varscan2
- ATP2C1 | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60756475; called by muse, mutect2, varscan2
- BCL6B | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.107); catalogued as rs768779742, COSV53427843; called by muse, mutect2, varscan2
- BCORL1 | c.585C>G p.N195K | Missense Mutation (SNP) | VAF 113/295 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV54396303; called by muse, mutect2, varscan2
- BET1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55992923; called by muse, mutect2, varscan2
- BTRC | c.1678C>T p.R560* (on ENST00000370187 / NM_033637.4; = p.R524* on NM_003939.5) | Nonsense Mutation (SNP) | VAF 39/67 reads (58%) | catalogued as rs375317445; called by muse, mutect2, varscan2
- C1QB | c.719T>C p.F240S | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59245374; called by muse, varscan2
- CABS1 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56733585; called by muse, mutect2, varscan2
- CCDC62 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV53433569; called by muse, mutect2, varscan2
- CCT8L2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV63462415, COSV63462950; called by muse, mutect2, varscan2
- CELA2A | c.755T>G p.F252C | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62747503; called by muse, mutect2, varscan2
- CFAP53 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs550993731, COSV68351359; called by muse, mutect2, varscan2
- CYP2S1 | c.1492C>T p.H498Y | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.092); catalogued as COSV59506113; called by muse, varscan2
- CYP3A5 | c.670+1G>A p.X224_splice | Splice Site (SNP) | VAF 13/30 reads (43%) | catalogued as COSV99769392; called by muse, mutect2, varscan2
- DAPK1 | c.2726C>T p.S909L | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs953872172, COSV63786529; called by muse, mutect2, varscan2
- DDX39A | c.371T>A p.L124Q | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54391570; called by muse, mutect2, varscan2
- DEPDC1B | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.79); PolyPhen benign (0.02); catalogued as COSV54010091, COSV99409389; called by muse, mutect2, varscan2
- DRD2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60757563; called by muse, mutect2, varscan2
- DSN1 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV65519179, COSV65519654; called by muse, mutect2, varscan2
- EBI3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV55690182; called by muse, mutect2, varscan2
- EPHB1 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs767340477, COSV67661665; called by muse, mutect2, varscan2
- ESX1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 107/275 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs144948361, COSV65424116; called by muse, mutect2, varscan2
- F11 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | catalogued as CM073033, COSV53001992; called by muse, mutect2, varscan2
- FAM135B | c.4030G>A p.E1344K | Missense Mutation (SNP) | VAF 348/503 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52725002; called by muse, varscan2
- FAM47A | c.638C>A p.P213Q | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as rs1348165787, COSV100649755, COSV60496653; called by muse, mutect2, varscan2
- FAP | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV51861870, COSV51867687; called by muse, mutect2, varscan2
- FAT4 | c.5477G>A p.R1826K | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as COSV58676480, COSV58685445; called by muse, mutect2, varscan2
- FBN1 | c.6304G>A p.E2102K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as COSV100353792; called by muse, mutect2, varscan2
- FEZ2 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as COSV59906486; called by muse, mutect2, varscan2
- FILIP1 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.83); catalogued as COSV52729700; called by muse, mutect2, varscan2
- FKRP | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV59358785, COSV59359829; called by muse, mutect2, varscan2
- FOXJ2 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV50818790; called by muse, mutect2, varscan2
- GAK | c.2743C>T p.L915F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58503771; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1611C>G p.D537E | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.262); catalogued as COSV54562274; called by muse, mutect2, varscan2
- HPR | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs766844305, COSV57182620; called by muse, mutect2, varscan2
- IGF2BP3 | c.1721C>A p.P574H | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as COSV51681921; called by muse, mutect2, varscan2
- IKBKE | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65624822; called by muse, mutect2, varscan2
- IL18RAP | c.1384+2T>C p.X462_splice | Splice Site (SNP) | VAF 17/52 reads (33%) | catalogued as COSV51825957; called by muse, mutect2, varscan2
- ILDR2 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs781739777, COSV54830974; called by muse, mutect2, varscan2
- KCNB2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 164/241 reads (68%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.96); catalogued as COSV73049036; called by muse, mutect2, varscan2
- KDR | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs866807777, COSV55762852; called by muse, mutect2, varscan2
- KIAA2013 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs749471034, COSV64860640; called by muse, mutect2
- L1CAM | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV62828104; called by muse, mutect2, varscan2
- LAMA1 | c.6886G>T p.G2296W | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67536986; called by muse, mutect2, varscan2
- LAMA3 | c.6944G>A p.R2315K (on ENST00000313654 / NM_198129.4; = p.R706K on NM_000227.6) | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.44); catalogued as COSV52530277, COSV52532553; called by muse, mutect2, varscan2
- LEFTY1 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.192); catalogued as COSV55282966; called by muse, mutect2, varscan2
- LHCGR | c.1658T>C p.V553A | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV54297025; called by muse, mutect2, varscan2
- MAGEB16 | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV67873931; called by mutect2, varscan2
- MALT1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as COSV61934891; called by muse, mutect2, varscan2
- MDN1 | c.10255C>T p.H3419Y | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV65521626; called by muse, mutect2
- MMP26 | c.734T>G p.I245S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.85); catalogued as COSV56172257; called by muse, mutect2, varscan2
- MMRN2 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV64400659; called by muse, mutect2, varscan2
- MUC16 | c.15355C>T p.P5119S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV67449282; called by muse, mutect2, varscan2
- MYO5C | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55906215; called by muse, mutect2, varscan2
- MYOM2 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1489890751, COSV100036363; called by muse, mutect2, varscan2
- NBPF1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 31/337 reads (9%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.001); catalogued as rs1320261980, COSV101236056; called by muse, mutect2, varscan2
- NEBL | c.2056-2A>T p.X686_splice | Splice Site (SNP) | VAF 25/63 reads (40%) | catalogued as COSV65802974; called by muse, mutect2, varscan2
- NLRP11 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV64086479, COSV64087360; called by muse, mutect2, varscan2
- NRROS | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV60745906; called by muse, mutect2, varscan2
- NUP210L | c.3251C>T p.P1084L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55147561; called by muse, mutect2, varscan2
- NYNRIN | c.3607C>T p.Q1203* | Nonsense Mutation (SNP) | VAF 53/89 reads (60%) | catalogued as COSV66842463; called by muse, mutect2, varscan2
- OR5AP2 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs999791836, COSV57257262; called by muse, mutect2, varscan2
- OR6C70 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs775257011, COSV100524352, COSV59244835; called by muse, mutect2, varscan2
- PCDHA3 | c.2321C>T p.P774L | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV63541409; called by muse, mutect2, varscan2
- PCDHB3 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 122/174 reads (70%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.945); catalogued as COSV50573699; called by muse, mutect2, varscan2
- PDZRN3 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55190687; called by muse, mutect2, varscan2
- PLCL2 | c.3148G>A p.E1050K (on ENST00000615277 / NM_001144382.2; = p.E924K on NM_015184.5) | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV67622121; called by muse, mutect2, varscan2
- PRKCG | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV54727739; called by muse, mutect2, varscan2
- PROM1 | c.2122G>A p.G708R | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.716); catalogued as rs779156936, COSV71699437, COSV71699678; called by muse, mutect2, varscan2
- PRSS58 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs147205406; called by muse, mutect2, varscan2
- PSAP | c.274A>T p.K92* | Nonsense Mutation (SNP) | VAF 23/33 reads (70%) | catalogued as COSV67550357; called by muse, mutect2, varscan2
- S100A7L2 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1164134401, COSV64195155; called by muse, mutect2, varscan2
- SCP2 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV65261175; called by muse, mutect2, varscan2
- SCRIB | c.2622C>A p.F874L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV57586905, COSV57587060; called by muse, mutect2, varscan2
- SERPINB2 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV55092448; called by muse, mutect2, varscan2
- SIN3A | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as COSV64582959; called by muse, mutect2, varscan2
- SIPA1L2 | c.4415C>T p.S1472L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.842); catalogued as rs150962063, COSV53384982; called by muse, mutect2, varscan2
- SIRPB1 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.332); catalogued as rs1421868708, COSV53538768; called by muse, mutect2, varscan2
- SLC22A10 | c.1494G>A p.W498* | Nonsense Mutation (SNP) | VAF 31/100 reads (31%) | catalogued as rs752543686, COSV60421277; called by muse, varscan2
- SLC26A7 | c.1832-1G>C p.X611_splice | Splice Site (SNP) | VAF 72/113 reads (64%) | catalogued as COSV52593342; called by muse, mutect2, varscan2
- SLC6A14 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64147054; called by muse, mutect2, varscan2
- SLC8A1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.346); catalogued as COSV60477579; called by muse, mutect2, varscan2
- SLC8A3 | c.2597C>T p.T866I (on ENST00000381269 / NM_183002.3; = p.T864I on NM_033262.4) | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53689546; called by muse, mutect2, varscan2
- SLC9A2 | c.1423C>T p.L475= | Splice Region (SNP) | VAF 62/159 reads (39%) | catalogued as rs750817058, COSV52132002; called by muse, mutect2, varscan2
- SLCO1C1 | c.679T>G p.C227G | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV56872624; called by muse, mutect2, varscan2
- SPAG17 | c.3238G>A p.E1080K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV60458862; called by muse, mutect2, varscan2
- STKLD1 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.985); catalogued as COSV64312706; called by muse, mutect2, varscan2
- SVEP1 | c.8954C>T p.S2985L | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as COSV52839285; called by muse, mutect2, varscan2
- TENM1 | c.4936G>A p.E1646K | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.492); catalogued as rs1316230881, COSV64431873; called by muse, mutect2, varscan2
- TMEM39A | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs1443841858, COSV59900403; called by muse, mutect2, varscan2
- TNXB | c.8135C>T p.T2712I (on ENST00000647633; = p.T2465I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as COSV64478982; called by muse, mutect2, varscan2
- TRAV8-1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 90/139 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.162); catalogued as rs1240240426; called by muse, mutect2, varscan2
- TTN | c.93799G>A p.D31267N (on ENST00000591111; = p.D23843N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | PolyPhen probably damaging (0.998); catalogued as rs267599023, COSV60028915; called by muse, mutect2, varscan2
- TTN | c.34573C>T p.P11525S (on ENST00000591111; = p.P10598S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/132 reads (34%) | PolyPhen benign (0.07); catalogued as COSV60062396; called by muse, mutect2, varscan2
- TTN | c.20192G>A p.R6731Q (on ENST00000591111; = p.R5804Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | PolyPhen possibly damaging (0.67); catalogued as rs148072021, COSV59923807, COSV59975784; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBXN2A | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV58336479; called by muse, mutect2, varscan2
- XKR4 | c.1577G>T p.C526F | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV100530269; called by muse, mutect2, varscan2
- XKR4 | c.1578T>G p.C526W | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV100530271; called by muse, mutect2, varscan2
- YLPM1 | c.3550C>T p.H1184Y | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as COSV53111808; called by muse, mutect2, varscan2
- ZBED9 | c.3833A>G p.E1278G | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV71729407; called by muse, mutect2, varscan2
- ZNF174 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.23); catalogued as rs377462126; called by muse, mutect2, varscan2
- ZNF684 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs146560433; called by muse, varscan2
- ZNF804A | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV100167703, COSV56448862; called by muse, mutect2, varscan2
- TRGC1 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- A2ML1 | c.1284G>A p.P428= | Silent (SNP) | VAF 50/145 reads (34%) | catalogued as rs753945399, COSV55286683; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACSM5 | c.894C>T p.P298= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV59371428, COSV59375331; called by muse, mutect2, varscan2
- AGRN | c.3597C>T p.S1199= | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as rs935849599, COSV65067869; called by muse, mutect2, varscan2
- APBB1IP | c.1179C>T p.S393= | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as COSV66132453; called by muse, mutect2, varscan2
- APLNR | c.1023G>A p.E341= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV57242621; called by muse, mutect2, varscan2
- APOB | c.11373C>T p.F3791= | Silent (SNP) | VAF 76/195 reads (39%) | catalogued as COSV51935316; called by muse, mutect2, varscan2
- ASXL3 | c.3708C>T p.V1236= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV52466136; called by muse, mutect2, varscan2
- B4GALNT3 | c.2277C>T p.N759= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV56752479; called by muse, mutect2, varscan2
- CD53 | c.546C>T p.F182= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV54761407; called by muse, mutect2, varscan2
- CKMT2 | c.126G>A p.R42= | Silent (SNP) | VAF 125/189 reads (66%) | catalogued as COSV54173367; called by muse, mutect2, varscan2
- CRISP3 | c.750G>A p.L250= (on ENST00000371159 / NM_001368123.1; = p.L232= on NM_006061.4) | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV53820308; called by muse, mutect2, varscan2
- CYP2C19 | c.936C>T p.L312= | Silent (SNP) | VAF 55/85 reads (65%) | catalogued as rs767006593, COSV64907754; called by muse, mutect2, varscan2
- FBN1 | c.6303G>A p.T2101= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV57311233; called by muse, mutect2, varscan2
- FBXW10 | c.1731G>A p.V577= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV57317140; called by muse, mutect2, varscan2
- FLG | c.3459C>T p.S1153= | Silent (SNP) | VAF 258/743 reads (35%) | catalogued as rs762134967, COSV64241837; called by muse, mutect2, varscan2
- FLNC | c.7896C>T p.S2632= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV50800070; called by muse, mutect2, varscan2
- GABRE | c.750G>A p.V250= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV64819686; called by muse, mutect2, varscan2
- GALNT18 | c.400C>A p.R134= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV57148601, COSV57149359; called by muse, mutect2, varscan2
- GINS3 | c.214C>T p.L72= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV58919760, COSV58919787; called by muse, mutect2, varscan2
- INTS9 | c.1818T>C p.I606= | Silent (SNP) | VAF 109/155 reads (70%) | catalogued as COSV68434160; called by muse, mutect2, varscan2
- KCNJ8 | c.462G>A p.L154= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV53716363; called by muse, mutect2, varscan2
- KRTAP10-11 | c.795C>T p.S265= | Silent (SNP) | VAF 60/158 reads (38%) | catalogued as COSV58177859, COSV58179059; called by muse, varscan2
- L1CAM | c.2217G>A p.R739= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs1557091086, COSV62828100; called by muse, mutect2, varscan2
- LAMA5 | c.6327C>T p.L2109= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV53360215; called by muse, mutect2, varscan2
- LINGO4 | c.756C>T p.L252= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV63214634; called by muse, mutect2, varscan2
- LRP4 | c.1614C>T p.A538= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV66135855; called by muse, mutect2, varscan2
- LRRC3B | c.309C>T p.I103= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs1358691804, COSV67521110; called by muse, mutect2, varscan2
- MPEG1 | c.165G>A p.R55= | Silent (SNP) | VAF 110/282 reads (39%) | catalogued as COSV57090779, COSV99915285; called by muse, mutect2, varscan2
- MPRIP | c.462G>A p.Q154= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV59048206; called by muse, mutect2, varscan2
- OR2M3 | c.903C>T p.F301= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as COSV101513401, COSV71759046; called by muse, mutect2, varscan2
- OR4C6 | c.846C>T p.P282= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV58602445, COSV58604010; called by muse, mutect2, varscan2
- OR8J3 | c.879G>A p.R293= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV56880768; called by muse, mutect2, varscan2
- PSG1 | c.561C>T p.L187= | Silent (SNP) | VAF 120/371 reads (32%) | catalogued as COSV54949211; called by muse, mutect2, varscan2
- RAG1 | c.9C>T p.A3= | Silent (SNP) | VAF 54/145 reads (37%) | catalogued as rs774066339, COSV55025300; called by muse, mutect2, varscan2
- SEZ6L | c.2928C>T p.Y976= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as rs761214039, COSV50664358; called by muse, mutect2, varscan2
- SLC24A2 | c.594C>T p.I198= | Silent (SNP) | VAF 28/45 reads (62%) | catalogued as rs758224147, COSV53865048; called by muse, mutect2, varscan2
- SLC27A2 | c.786C>T p.I262= | Silent (SNP) | VAF 56/152 reads (37%) | catalogued as rs868276860, COSV51059001; called by muse, mutect2, varscan2
- STK11IP | c.2154C>T p.L718= | Silent (SNP) | VAF 86/244 reads (35%) | catalogued as rs377181724; called by muse, mutect2, varscan2
- TM7SF3 | c.978C>T p.I326= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV58002316; called by muse, mutect2, varscan2
- TMPRSS11F | c.648G>A p.G216= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as COSV62466506; called by muse, mutect2, varscan2
- TRO | c.3282C>T p.I1094= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs761876521, COSV51501547; called by muse, mutect2, varscan2
- TTN | c.17370C>T p.F5790= (on ENST00000591111; = p.F4863= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV60062419; called by muse, mutect2
- TTN | c.13719C>T p.F4573= (on ENST00000591111; = p.F3646= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1260191732, COSV60003173, COSV60062433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USHBP1 | c.792C>T p.P264= | Silent (SNP) | VAF 61/113 reads (54%) | catalogued as COSV53103586; called by muse, mutect2, varscan2
- VN1R2 | c.339C>T p.F113= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV59038294; called by muse, mutect2, varscan2
- WDR44 | c.792G>A p.L264= | Silent (SNP) | VAF 82/239 reads (34%) | catalogued as COSV54163537; called by muse, mutect2, varscan2
- ZFPM2 | c.2010G>A p.V670= | Silent (SNP) | VAF 41/64 reads (64%) | catalogued as COSV65873689; called by muse, mutect2, varscan2
- AL133467.6 | n.43C>A | RNA (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- GSG1 | c.481+18G>A | Intron (SNP) | VAF 23/65 reads (35%) | catalogued as rs148537880; called by muse, mutect2, varscan2
- MIR125B1 | n.83C>T | RNA (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- XIST | n.8755C>T | RNA (SNP) | VAF 12/29 reads (41%) | catalogued as rs1162704710; called by muse, mutect2, varscan2
